Somatic mutation profile of tumor specimen 0DWI1E from CCDI case PBCNIL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.3 years (1,203 days).
Specimen 0DWI1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe233cf8-8815-44cd-9742-9f4c47fdbc66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c538528-ff79-4bca-8066-91f7e4469238

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 3, Intron 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 384/513 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ARMH4 | c.1983C>G p.I661M | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1264750967; called by muse, mutect2, varscan2
- BTBD9 | c.1598C>A p.A533D | Missense Mutation (SNP) | VAF 144/488 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58425236; called by mutect2, varscan2
- CMIP | c.1085C>T p.P362L (on ENST00000537098 / NM_198390.2; = p.P268L on NM_030629.3) | Missense Mutation (SNP) | VAF 269/790 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs760254009, COSV67699162; called by muse, mutect2, varscan2
- GLI3 | c.2881G>T p.G961W | Missense Mutation (SNP) | VAF 136/555 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs745986297, COSV104431689; called by muse, mutect2, varscan2
- MINAR1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 52/504 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs762688621, COSV59581209, COSV59584444; called by muse, mutect2, varscan2
- OR5H14 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 246/840 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1184502493, COSV101454256, COSV71193845; called by mutect2, varscan2
- PCDHB12 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 44/698 reads (6%) | catalogued as COSV53396599; called by muse, mutect2
- RXFP2 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 187/1634 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs374003152; called by muse, mutect2, varscan2
- SHISA3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1357009225, COSV59979722; called by muse, mutect2, varscan2
- SRSF5 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 171/589 reads (29%) | catalogued as COSV67936734; called by muse, mutect2, varscan2
- TARS3 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 47/384 reads (12%) | catalogued as rs983525726; called by muse, mutect2, varscan2
- TAS2R16 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 502/935 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.245); catalogued as rs372127324; called by muse, mutect2
- ZNF746 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as rs1251276250; called by muse, mutect2
- ARSI | c.161C>G p.T54R | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP7A | c.485A>T p.D162V | Missense Mutation (SNP) | VAF 68/682 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2
- AUH | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 316/935 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C8orf82 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 174/930 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CBLN4 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 74/922 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CUBN | c.5078G>C p.R1693P | Missense Mutation (SNP) | VAF 184/682 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- GATAD1 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST1 | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 178/617 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- IMPACT | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMAA | c.562+1G>C p.X188_splice | Splice Site (SNP) | VAF 144/404 reads (36%) | called by muse, mutect2, varscan2
- MTMR1 | c.1513G>C p.V505L | Missense Mutation (SNP) | VAF 76/1744 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- NONO | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 171/545 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NOS1 | c.3483C>G p.I1161M | Missense Mutation (SNP) | VAF 108/373 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PIK3R6 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 199/551 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP6R1 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOXF2B | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 149/682 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA7 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 288/806 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SIAH3 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 128/1392 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2
- STRN | c.146T>A p.L49H | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADGRV1 | c.8607G>C p.L2869= | Silent (SNP) | VAF 84/1023 reads (8%) | called by muse, mutect2
- CCN1 | c.1065C>T p.C355= | Silent (SNP) | VAF 32/851 reads (4%) | called by muse, mutect2
- DACH2 | c.1380C>A p.T460= | Silent (SNP) | VAF 286/693 reads (41%) | called by muse, mutect2, varscan2
- INVS | c.2367C>A p.A789= | Silent (SNP) | VAF 136/420 reads (32%) | catalogued as rs761619797; called by muse, mutect2, varscan2
- JCAD | c.1050G>C p.P350= | Silent (SNP) | VAF 49/421 reads (12%) | catalogued as COSV64758807; called by muse, mutect2, varscan2
- KLHL13 | c.93A>G p.A31= | Silent (SNP) | VAF 217/667 reads (33%) | called by muse, mutect2, varscan2
- MAPK4 | c.1215C>T p.S405= | Silent (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- MUC5B | c.16704C>A p.T5568= | Silent (SNP) | VAF 118/416 reads (28%) | called by muse, mutect2, varscan2
- MXRA5 | c.2310G>A p.R770= | Silent (SNP) | VAF 259/724 reads (36%) | called by muse, mutect2, varscan2
- RASEF | c.1053C>T p.D351= | Silent (SNP) | VAF 50/922 reads (5%) | called by muse, mutect2
- VASN | c.1551C>T p.L517= | Silent (SNP) | VAF 106/358 reads (30%) | catalogued as rs1351697591; called by muse, mutect2, varscan2
- ZMYND15 | c.1485G>T p.V495= | Silent (SNP) | VAF 110/195 reads (56%) | called by mutect2, varscan2
- ARTN | c.61-25G>T | Intron (SNP) | VAF 115/513 reads (22%) | catalogued as rs1219858531; called by muse, mutect2, varscan2
- C5AR2 | c.*88T>G | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- CACNB2 | c.213+110340T>C | Intron (SNP) | VAF 52/464 reads (11%) | called by muse, mutect2, varscan2
